Somatic mutation profile of tumor specimen C3L-10132-01 (aliquot CPT0547860009) from CPTAC case C3L-10132, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 73.9 years (27,010 days).
Specimen C3L-10132-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6130823-2f41-4c89-8306-7fd6ad3ce7bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-10132-31 (Blood Derived Normal), aliquot CPT0548010004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df1d801e-1e0e-4e56-9f83-1e2af61ee21b

The open-access MAF lists 1,581 somatic variants for this specimen: 1,161 protein-altering or splice-affecting, 371 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 832, Silent 371, Frame Shift Del 202, Frame Shift Ins 51, Nonsense Mutation 35, Intron 30, In Frame Del 17, Splice Site 11, Splice Region 10, 3'UTR 7, 3'Flank 5, 5'UTR 5.

Variants (750 of 1,581; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by pindel, varscan2
- BRCA2 | c.5351dup p.N1784Kfs*3 | Frame Shift Ins (INS) | VAF 54/208 reads (26%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CDH23 | c.3241C>T p.R1081* | Nonsense Mutation (SNP) | VAF 70/272 reads (26%) | catalogued as rs866435331, CM105103; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GABRB2 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 81/310 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1554093884, COSV50956265; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MKRN3 | c.482dup p.A162Gfs*15 | Frame Shift Ins (INS) | VAF 61/364 reads (17%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 34/174 reads (20%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 74/312 reads (24%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTEN | c.802-3_804delinsAGGACA p.X268_splice | Splice Site (ONP) | VAF 9/66 reads (14%) | hotspot (GDC flag); called by pindel, varscan2*
- TBX6 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 67/276 reads (24%) | catalogued as rs201620629, CM154507; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4442A>T p.H1481L | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs754029639; called by muse, mutect2, varscan2
- ABCA12 | c.4841del p.G1614Efs*49 (on ENST00000272895 / NM_173076.3; = p.G1296Efs*49 on NM_015657.3) | Frame Shift Del (DEL) | VAF 82/384 reads (21%) | catalogued as COSV55971502, COSV55972486; called by mutect2, pindel, varscan2
- ABCA5 | c.911del p.F304Sfs*12 | Frame Shift Del (DEL) | VAF 18/164 reads (11%) | catalogued as rs776887626; called by mutect2, pindel, varscan2
- ABCC8 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 90/375 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as CM129772, COSV100217763; called by muse, mutect2, varscan2
- ABI3BP | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52550859; called by muse, mutect2, varscan2
- AC011448.1 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs200873378; called by muse, mutect2, varscan2
- AC069544.2 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766836506; called by muse, mutect2, varscan2
- ACACB | c.4762G>A p.D1588N | Missense Mutation (SNP) | VAF 87/339 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753780968; called by muse, mutect2, varscan2
- ACADM | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1324329442, CM125805, COSV100273478; called by muse, mutect2, varscan2
- ACP4 | c.114A>G p.V38= | Splice Region (SNP) | VAF 52/276 reads (19%) | catalogued as rs888020564; called by muse, mutect2, varscan2
- ACVR2B | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100754199; called by muse, mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 56/270 reads (21%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAMTS9 | c.4995del p.S1666Vfs*7 | Frame Shift Del (DEL) | VAF 66/406 reads (16%) | catalogued as rs754786025; called by mutect2, pindel, varscan2
- ADAP2 | c.379del p.E127Kfs*24 | Frame Shift Del (DEL) | VAF 56/239 reads (23%) | catalogued as COSV58297212; called by mutect2, pindel, varscan2
- ADGRB2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 125/528 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs372925356; called by muse, mutect2, varscan2
- ADRA2B | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 113/413 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69787296; called by muse, mutect2, varscan2
- ADRB3 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 125/586 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456854445; called by muse, mutect2, varscan2
- AFF2 | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 233/580 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782758944, COSV53993153; called by muse, mutect2, varscan2
- AHSG | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.087); catalogued as COSV99890160; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 76/240 reads (32%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALDH9A1 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs372002782, COSV61339870; called by muse, mutect2, varscan2
- ALG8 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs1202671357; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 103/435 reads (24%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ALX1 | c.568A>G p.R190G | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV100374419; called by muse, mutect2, varscan2
- AMBRA1 | c.2037G>A p.M679I (on ENST00000458649 / NM_001367468.1; = p.M589I on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV54059613; called by muse, mutect2, varscan2
- AMER3 | c.1637dup p.R547Qfs*64 | Frame Shift Ins (INS) | VAF 110/399 reads (28%) | catalogued as rs893863661; called by mutect2, pindel, varscan2
- AMOTL1 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1254016891; called by muse, mutect2, varscan2
- AMPD1 | c.2203G>T p.G735C | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62415063, COSV62415300; called by muse, mutect2, varscan2
- ANAPC13 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs753958208, COSV59677084; called by muse, varscan2
- ANGPTL3 | c.1284_1286del p.R430del | In Frame Del (DEL) | VAF 36/178 reads (20%) | catalogued as rs748938254; called by pindel, varscan2
- ANKRD26 | c.1110dup p.E371Rfs*5 | Frame Shift Ins (INS) | VAF 24/138 reads (17%) | catalogued as rs775948884; called by mutect2, varscan2
- ANKRD52 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as rs758190924, COSV57284203; called by muse, mutect2, varscan2
- ANKRD6 | c.1667C>T p.P556L (on ENST00000339746 / NM_001242809.2; = p.P551L on NM_014942.4) | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as rs1196610897; called by muse, mutect2, varscan2
- ANKS3 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 87/396 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs1176276798, COSV58512145; called by muse, mutect2, varscan2
- ANO4 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs1368161587; called by muse, mutect2, varscan2
- AP1S3 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 96/412 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs373484762; called by muse, mutect2, varscan2
- APC | c.1100_1101del p.S367Cfs*10 | Frame Shift Del (DEL) | VAF 70/406 reads (17%) | catalogued as rs387906237; called by pindel, varscan2
- ARAP1 | c.2675G>A p.R892H (on ENST00000393609 / NM_001040118.2; = p.R647H on NM_015242.4) | Missense Mutation (SNP) | VAF 85/366 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368512511; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 29/149 reads (19%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 50/239 reads (21%) | catalogued as rs774148781; called by mutect2, varscan2
- ARFGEF2 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 75/331 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs758071330; called by muse, mutect2, varscan2
- ARHGEF17 | c.5489G>A p.R1830Q | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs373679245; called by muse, mutect2, varscan2
- ARHGEF33 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 140/513 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.522); catalogued as rs1361913464; called by muse, mutect2, varscan2
- ARHGEF40 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs200438221; called by muse, mutect2, varscan2
- ARID1A | c.1963G>T p.G655* | Nonsense Mutation (SNP) | VAF 85/318 reads (27%) | catalogued as COSV61377758; called by muse, mutect2, varscan2
- ARID3B | c.1643G>A p.R548Q (on ENST00000622429 / NM_001307939.1; = p.R547Q on NM_006465.4) | Missense Mutation (SNP) | VAF 151/358 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs781608342, COSV60556401; called by muse, varscan2
- ARID5A | c.1667del p.P556Qfs*145 | Frame Shift Del (DEL) | VAF 117/471 reads (25%) | catalogued as rs1388296178; called by mutect2, pindel, varscan2
- ATG2A | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1299595904, COSV65966919; called by muse, mutect2, varscan2
- ATG3 | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111381655; called by muse, mutect2, varscan2
- ATP8B2 | c.2228G>A p.R743Q (on ENST00000672630; = p.R710Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs769777681; called by muse, mutect2, varscan2
- AUTS2 | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV61392844; called by mutect2, varscan2
- AVPR1A | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146832; called by muse, mutect2, varscan2
- BAG4 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs757197258, COSV54863049; called by muse, mutect2, varscan2
- BARHL1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55037165, COSV55039029; called by muse, mutect2, varscan2
- BBS5 | c.709del p.I237* | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | catalogued as rs1471916487; called by mutect2, pindel, varscan2
- BCL11A | c.1724C>T p.P575L (on ENST00000335712 / NM_001365609.1; = p.P609L on NM_018014.4) | Missense Mutation (SNP) | VAF 115/485 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1466757077, COSV59625455; called by muse, mutect2, varscan2
- BCL9 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 96/541 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs782230804, COSV52347514; called by muse, mutect2, varscan2
- BCL9L | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); catalogued as rs762366458, COSV100599349; called by muse, mutect2, varscan2
- BDKRB2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 108/437 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.198); catalogued as rs138076769; called by muse, mutect2, varscan2
- BEGAIN | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 122/558 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.649); catalogued as rs139028547; called by muse, varscan2
- BEND4 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs201512414, COSV72468903; called by muse, mutect2, varscan2
- BHLHE22 | c.590del p.P197Rfs*62 | Frame Shift Del (DEL) | VAF 61/302 reads (20%) | catalogued as rs1193188760; called by pindel, varscan2
- BICRA | c.2516del p.N839Tfs*3 | Frame Shift Del (DEL) | VAF 36/172 reads (21%) | catalogued as COSV67604570; called by mutect2, pindel, varscan2
- BICRA | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 68/377 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs756323742, COSV101194273; called by muse, varscan2
- BMP3 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51088792; called by muse, mutect2
- BMP4 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV99817196; called by muse, mutect2
- BSPRY | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.259); catalogued as rs936239979; called by muse, mutect2
- BSX | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 130/439 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs867818183, COSV58005694; called by muse, mutect2, varscan2
- BTN3A1 | c.833del p.K278Rfs*13 | Frame Shift Del (DEL) | VAF 34/195 reads (17%) | catalogued as rs35139329; called by mutect2, pindel, varscan2
- BTN3A2 | c.949del p.I317Sfs*4 | Frame Shift Del (DEL) | VAF 55/270 reads (20%) | catalogued as COSV62687981; called by mutect2, pindel, varscan2
- C12orf43 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 20/295 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.217); catalogued as rs1156590337; called by muse, mutect2
- C15orf39 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 30/528 reads (6%) | catalogued as rs1174863337, COSV100641125; called by muse, mutect2
- C15orf40 | c.457del p.T153Hfs*6 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | catalogued as rs751372654; called by mutect2, varscan2
- C17orf113 | c.1910dup p.H638Pfs*16 | Frame Shift Ins (INS) | VAF 36/208 reads (17%) | catalogued as rs1188751238; called by mutect2, varscan2
- C1QTNF4 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1478395685, COSV56783790; called by muse, mutect2, varscan2
- CACNA1A | c.6898del p.R2300Gfs*9 | Frame Shift Del (DEL) | VAF 40/148 reads (27%) | catalogued as rs1180079360; called by pindel, varscan2
- CACNA1B | c.393C>T p.D131= | Splice Region (SNP) | VAF 45/195 reads (23%) | catalogued as rs774589225, COSV53113802; called by muse, mutect2, varscan2
- CACNA1C | c.6571C>T p.R2191W (on ENST00000399634 / NM_001167625.1; = p.R2120W on NM_000719.7) | Missense Mutation (SNP) | VAF 107/494 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV59708706; called by muse, mutect2, varscan2
- CACNA1I | c.4346G>A p.R1449H | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1472537135, COSV60810026; called by muse, mutect2, varscan2
- CACNA2D3 | c.40del p.A14Pfs*29 | Frame Shift Del (DEL) | VAF 32/192 reads (17%) | catalogued as rs1477361405; called by mutect2, pindel, varscan2
- CAD | c.6191G>A p.R2064H | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53025540; called by muse, mutect2, varscan2
- CALHM1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 116/508 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs778025044; called by muse, mutect2, varscan2
- CARNS1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as rs768346960, COSV57129803; called by muse, mutect2, varscan2
- CASKIN1 | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs1295488739; called by muse, mutect2, varscan2
- CBFA2T3 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 100/450 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs562711336; called by muse, mutect2, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 26/151 reads (17%) | catalogued as rs1256378164; called by pindel, varscan2
- CCDC73 | c.657del p.A220Qfs*5 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | catalogued as rs749079180; called by mutect2, varscan2
- CCDC97 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 86/483 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.697); catalogued as rs760623895; called by muse, mutect2, varscan2
- CCNY | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 104/379 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as rs755354910; called by muse, mutect2, varscan2
- CCSER1 | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 83/339 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs779227303, COSV61427529; called by muse, mutect2, varscan2
- CDC23 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV67509744; called by muse, mutect2, varscan2
- CDCA7 | c.878G>A p.R293Q (on ENST00000347703 / NM_145810.3; = p.R372Q on NM_031942.5) | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV60720188; called by muse, varscan2
- CDCA7 | c.970C>T p.R324* (on ENST00000347703 / NM_145810.3; = p.R403* on NM_031942.5) | Nonsense Mutation (SNP) | VAF 86/284 reads (30%) | catalogued as COSV100143316; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 100/480 reads (21%) | catalogued as rs752398646; called by pindel, varscan2
- CELSR3 | c.6200G>A p.R2067Q | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.166); catalogued as rs573133214, COSV50840343; called by muse, mutect2, varscan2
- CFAP54 | c.1687A>T p.K563* | Nonsense Mutation (SNP) | VAF 38/136 reads (28%) | catalogued as rs762079380, COSV54351584; called by mutect2, varscan2
- CGNL1 | c.2827C>T p.R943W | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778467834, COSV55567766; called by muse, mutect2, varscan2
- CHD6 | c.4645C>T p.R1549* | Nonsense Mutation (SNP) | VAF 110/488 reads (23%) | catalogued as COSV64695652; called by muse, mutect2, varscan2
- CHRD | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV52607731; called by muse, mutect2, varscan2
- CKAP5 | c.3089G>A p.R1030Q | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100370713; called by muse, mutect2, varscan2
- CKAP5 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as rs1037964579; called by muse, mutect2
- CLMP | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV71649476; called by muse, mutect2
- CLPB | c.995A>G p.E332G | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs745539947; called by muse, mutect2
- CLU | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs1446623022, COSV57066892; called by muse, mutect2, varscan2
- CMYA5 | c.11828G>A p.G3943D | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1413337212; called by muse, mutect2, varscan2
- CNMD | c.193T>C p.W65R | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs752392381; called by muse, mutect2, varscan2
- COA8 | c.41dup p.L15Sfs*40 | Frame Shift Ins (INS) | VAF 55/284 reads (19%) | catalogued as rs759966247; called by mutect2, pindel, varscan2
- COL11A2 | c.3032del p.P1011Lfs*334 (on ENST00000341947 / NM_080680.3; = p.P904Lfs*334 on NM_080679.2) | Frame Shift Del (DEL) | VAF 92/350 reads (26%) | catalogued as rs1363500354; called by mutect2, pindel, varscan2
- COL22A1 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 87/613 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs139591204; called by muse, mutect2, varscan2
- COL4A1 | c.10del p.R4Gfs*41 | Frame Shift Del (DEL) | VAF 48/336 reads (14%) | catalogued as rs1373364260; called by mutect2, pindel, varscan2
- COL4A2 | c.1687G>A p.G563S | Missense Mutation (SNP) | VAF 92/384 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs905241418, COSV64630621; called by muse, mutect2, varscan2
- CORO7 | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs145925246; called by muse, mutect2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 87/315 reads (28%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRYBA2 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs775022036, COSV55388104; called by mutect2, varscan2
- CSF1 | c.1622G>T p.S541I | Missense Mutation (SNP) | VAF 93/356 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60034827; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 52/261 reads (20%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTU1 | c.845C>G p.P282R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs1018653314; called by mutect2, varscan2
- CXADR | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as rs368675196; called by muse, mutect2, varscan2
- CXCL12 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs529221485, COSV59107282; called by muse, mutect2, varscan2
- CXorf65 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 102/368 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs781010981; called by muse, varscan2
- DCAF6 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs200843977; called by muse, mutect2, varscan2
- DCC | c.218A>G p.K73R | Missense Mutation (SNP) | VAF 85/382 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs141272344; called by muse, mutect2, varscan2
- DCLK1 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 58/227 reads (26%) | catalogued as COSV55212077, COSV55215398; called by muse, varscan2
- DCLK1 | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 80/296 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as COSV55195853, COSV99709434; called by muse, mutect2, varscan2
- DCST2 | c.360C>A p.S120R | Missense Mutation (SNP) | VAF 76/433 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs779665410, COSV55055263; called by muse, mutect2, varscan2
- DECR1 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 76/316 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760262701; called by muse, mutect2, varscan2
- DGKG | c.1413dup p.P472Afs*10 | Frame Shift Ins (INS) | VAF 71/266 reads (27%) | catalogued as rs773805927; called by mutect2, pindel, varscan2
- DHRS1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 90/346 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs780120437; called by muse, mutect2, varscan2
- DISP2 | c.4028C>T p.A1343V | Missense Mutation (SNP) | VAF 26/465 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1455503989; called by muse, mutect2
- DLC1 | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 72/372 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as COSV104370981; called by mutect2, varscan2
- DMD | c.4088A>C p.K1363T | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.059); catalogued as COSV63732568, COSV63756777; called by muse, mutect2, varscan2
- DNAH10 | c.7915C>T p.R2639C (on ENST00000409039; = p.R2578C on NM_207437.3) | Missense Mutation (SNP) | VAF 147/588 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774602539, COSV69005161; called by muse, mutect2, varscan2
- DNAH12 | c.8203G>A p.V2735I (on ENST00000351747; = p.V3603I on NM_001366028.2) | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.19); catalogued as rs1471001608; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH5 | c.10500del p.E3501Kfs*18 | Frame Shift Del (DEL) | VAF 46/198 reads (23%) | catalogued as COSV54213332; called by mutect2, pindel, varscan2
- DNAH5 | c.10193G>A p.R3398H | Missense Mutation (SNP) | VAF 70/325 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs201554319, COSV54240792; called by muse, mutect2, varscan2
- DNAJB5 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 96/385 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs769407757; called by muse, mutect2, varscan2
- DNAJC21 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.238); catalogued as rs754153100, COSV57759557; called by muse, mutect2, varscan2
- DQX1 | c.1562A>G p.H521R | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs895669216; called by muse, mutect2, varscan2
- DRD4 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs1454807628; called by muse, mutect2, varscan2
- DVL2 | c.2011C>A p.P671T | Missense Mutation (SNP) | VAF 165/673 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.562); catalogued as rs750439416; called by muse, mutect2, varscan2
- DXO | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 84/364 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200784745, CM124440; called by muse, varscan2
- E2F8 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147218768; called by muse, mutect2, varscan2
- ECM1 | c.1045T>C p.C349R | Missense Mutation (SNP) | VAF 142/400 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777173556, COSV60871768; called by muse, mutect2, varscan2
- EFR3B | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 77/388 reads (20%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.617); catalogued as rs1194664981; called by muse, mutect2, varscan2
- EFTUD2 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1179821885, COSV68183102; called by muse, mutect2, varscan2
- EGR4 | c.1340C>T p.P447L (on ENST00000545030; = p.P344L on NM_001965.4) | Missense Mutation (SNP) | VAF 79/335 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs760905025; called by muse, mutect2, varscan2
- EHD3 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.166); catalogued as rs372292180; called by muse, mutect2, varscan2
- EHHADH | c.2100dup p.L701Tfs*20 | Frame Shift Ins (INS) | VAF 68/322 reads (21%) | catalogued as rs747455018; called by mutect2, varscan2
- ELANE | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs750859137; called by muse, mutect2, varscan2
- ELK1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 52/742 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55952687; called by muse, mutect2
- ELK3 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 110/421 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs752081794, COSV57387626; called by muse, mutect2, varscan2
- EMC1 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs767596155; called by muse, mutect2, varscan2
- EML6 | c.4070del p.K1357Rfs*9 | Frame Shift Del (DEL) | VAF 38/156 reads (24%) | catalogued as rs746682537; called by mutect2, varscan2
- ENTPD3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV57196865; called by muse, mutect2, varscan2
- EPHA7 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 75/370 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs1402331883, COSV100994200, COSV65194736; called by muse, mutect2, varscan2
- EPM2AIP1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 110/442 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV99212667; called by muse, mutect2, varscan2
- EPN1 | c.1707del p.N570Tfs*31 (on ENST00000270460 / NM_001321263.1; = p.N544Tfs*31 on NM_013333.3) | Frame Shift Del (DEL) | VAF 64/341 reads (19%) | catalogued as COSV50046705; called by mutect2, pindel, varscan2
- ERBB2 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 123/473 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54066669; called by muse, mutect2, varscan2
- ERICH6B | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs907953283, COSV53922914; called by muse, mutect2, varscan2
- ERICH6B | c.950del p.K317Rfs*18 | Frame Shift Del (DEL) | VAF 54/202 reads (27%) | catalogued as rs754232917, COSV100074795; called by mutect2, varscan2
- ESM1 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 123/546 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as rs1010100019, COSV67318724; called by muse, mutect2, varscan2
- FAM160B2 | c.305del p.P102Qfs*79 | Frame Shift Del (DEL) | VAF 54/294 reads (18%) | catalogued as rs747272499; called by mutect2, pindel, varscan2
- FAM167B | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 108/466 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as rs368986976, COSV61111676; called by muse, mutect2, varscan2
- FAM169A | c.1726del p.V576Yfs*16 | Frame Shift Del (DEL) | VAF 62/348 reads (18%) | catalogued as rs745655488; called by mutect2, pindel, varscan2
- FAM171A1 | c.2512C>T p.R838W | Missense Mutation (SNP) | VAF 95/409 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs145341684; called by muse, mutect2, varscan2
- FAM184A | c.1662C>A p.H554Q | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs770902577; called by muse, mutect2, varscan2
- FAM71B | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 20/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248503849; called by muse, mutect2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 62/372 reads (17%) | catalogued as rs754952124; called by mutect2, pindel, varscan2
- FASN | c.5212G>A p.G1738R | Missense Mutation (SNP) | VAF 68/376 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774809206; called by muse, mutect2, varscan2
- FASTK | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs201985792, COSV52542440; called by muse, mutect2, varscan2
- FBF1 | c.739C>T p.R247* (on ENST00000586717; = p.R261* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 32/507 reads (6%) | catalogued as rs1420343806; called by muse, mutect2
- FBLIM1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 19/287 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs138158787, COSV60030143; called by muse, mutect2
- FBN2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52493432; called by muse, mutect2, varscan2
- FBN3 | c.2259dup p.G754Rfs*69 | Frame Shift Ins (INS) | VAF 62/262 reads (24%) | catalogued as rs755836480; called by mutect2, varscan2
- FBXO11 | c.1530del p.G511Efs*6 (on ENST00000403359 / NM_001190274.2; = p.G427Efs*6 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 65/275 reads (24%) | catalogued as COSV57016953; called by mutect2, pindel, varscan2
- FBXO24 | c.199C>T p.R67C (on ENST00000241071 / NM_033506.3; = p.R105C on NM_012172.5) | Missense Mutation (SNP) | VAF 82/377 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs150933909; called by muse, mutect2, varscan2
- FBXO24 | c.593G>A p.R198H (on ENST00000241071 / NM_033506.3; = p.R236H on NM_012172.5) | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs578251894, COSV53825046; called by muse, mutect2, varscan2
- FBXO38 | c.3472C>T p.R1158C (on ENST00000340253 / NM_205836.3; = p.R1083C on NM_030793.5) | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1273071907, COSV57026031; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FCHO2 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 61/356 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as rs953996152; called by muse, mutect2, varscan2
- FERMT3 | c.516C>T p.G172= | Splice Region (SNP) | VAF 88/310 reads (28%) | catalogued as rs1484992100, COSV54180109; called by muse, mutect2, varscan2
- FGF17 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 73/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs765805432; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 83/352 reads (24%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FLG | c.5587A>C p.S1863R | Missense Mutation (SNP) | VAF 88/462 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV64235589; called by muse, mutect2, varscan2
- FMN2 | c.3044C>T p.P1015L | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1210528843; called by muse, varscan2
- FMO2 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as rs752948394; called by muse, mutect2, varscan2
- FRMD4A | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 88/381 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs1298783765; called by muse, mutect2, varscan2
- FRMPD4 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 124/583 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.247); catalogued as rs748144907, COSV101042194; ClinVar: benign; called by muse, mutect2, varscan2
- FRZB | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 110/408 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766528949; called by muse, mutect2, varscan2
- FSIP2 | c.19584del p.K6528Nfs*5 | Frame Shift Del (DEL) | VAF 25/183 reads (14%) | catalogued as rs781034813; called by mutect2, pindel, varscan2
- FZD3 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53537611; called by muse, mutect2, varscan2
- GABRQ | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 112/567 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782673532; called by muse, mutect2, varscan2
- GALNT10 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs147745456; called by muse, varscan2
- GALNT15 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 84/394 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs760843155; called by muse, mutect2, varscan2
- GALNT6 | c.1557del p.K520Sfs*79 | Frame Shift Del (DEL) | VAF 60/287 reads (21%) | catalogued as rs748677519, COSV62541669; called by mutect2, pindel, varscan2
- GAS7 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.197); catalogued as COSV71564630; called by muse, varscan2
- GATM | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1479969521; ClinVar: uncertain significance; called by muse, mutect2
- GET3 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 99/364 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs779152850; called by muse, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 96/388 reads (25%) | catalogued as rs759448855, COSV99954330; called by mutect2, varscan2
- GLI1 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 87/380 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as rs147758271, COSV99954840; called by muse, mutect2, varscan2
- GLI3 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs751057099, COSV67885486; called by muse, varscan2
- GLRA4 | c.1050A>G p.I350M | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100129126; called by muse, mutect2
- GLS2 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs370475281; called by muse, mutect2, varscan2
- GMEB2 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 167/574 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.041); catalogued as rs745644457; called by muse, mutect2, varscan2
- GMIP | c.1715C>T p.T572M | Missense Mutation (SNP) | VAF 57/330 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52554664; called by muse, mutect2, varscan2
- GPR173 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 165/603 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.934); catalogued as rs782340108, COSV60234702; called by muse, mutect2, varscan2
- GPR27 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.267); catalogued as rs1318973924; called by muse, mutect2, varscan2
- GRAMD1A | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769359996; called by muse, mutect2, varscan2
- GRAMD4 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 100/443 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs374106125; called by muse, mutect2, varscan2
- GRHL2 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 81/383 reads (21%) | catalogued as rs1350802574, COSV52544849; called by muse, mutect2, varscan2
- GRID1 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 77/319 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.624); catalogued as rs773050428, COSV60032121; called by muse, mutect2, varscan2
- GRM6 | c.426dup p.E143Rfs*46 | Frame Shift Ins (INS) | VAF 70/336 reads (21%) | catalogued as rs1227814608; called by pindel, varscan2
- GUCY1A2 | c.1089C>A p.C363* | Nonsense Mutation (SNP) | VAF 92/340 reads (27%) | catalogued as COSV56484512; called by muse, mutect2, varscan2
- GZF1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 84/360 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs141101185; called by muse, varscan2
- HDAC4 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 17/464 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553617643, COSV61867383; ClinVar: uncertain significance; called by muse, mutect2
- HERC5 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1207210112, COSV52042859; called by muse, mutect2, varscan2
- HHIPL1 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 92/377 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.428); catalogued as rs1196514949; called by muse, mutect2, varscan2
- HIVEP1 | c.93del p.E32Kfs*17 | Frame Shift Del (DEL) | VAF 30/112 reads (27%) | catalogued as rs1561928340; called by mutect2, pindel, varscan2
- HLA-DRA | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs201781094, COSV66622681; called by muse, mutect2, varscan2
- HOXA11 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 156/548 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs775915366; called by muse, mutect2, varscan2
- HOXB5 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs755209108; called by muse, mutect2, varscan2
- HRAS | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 122/497 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as rs749674880, COSV54241667; called by muse, varscan2
- HS3ST3B1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100714416, COSV62907308; called by muse, mutect2, varscan2
- HS6ST3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 21/466 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1226165605, COSV100940109; called by muse, mutect2
- HSPA6 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 101/466 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as rs371251812; called by muse, mutect2, varscan2
- HTATSF1 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 101/409 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs757002909; called by muse, mutect2, varscan2
- IFRD1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50044256; called by muse, mutect2, varscan2
- IFT122 | c.896del p.G299Vfs*71 (on ENST00000348417 / NM_052989.3; = p.G240Vfs*71 on NM_018262.4) | Frame Shift Del (DEL) | VAF 89/342 reads (26%) | catalogued as rs778534085; called by mutect2, pindel, varscan2
- IFT57 | c.175_177del p.E59del | In Frame Del (DEL) | VAF 42/222 reads (19%) | catalogued as rs752137963; called by pindel, varscan2
- IGF2BP1 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as rs745882726, COSV51736438; called by muse, mutect2, varscan2
- IGFALS | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 126/524 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs769060887; called by muse, mutect2, varscan2
- IGHMBP2 | c.1936A>G p.I646V | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1350592778; called by muse, mutect2, varscan2
- ILKAP | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 69/357 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99611161; called by muse, mutect2, varscan2
- INF2 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as rs544171369; called by muse, mutect2, varscan2
- INKA2 | c.825del p.T276Qfs*25 | Frame Shift Del (DEL) | VAF 83/350 reads (24%) | catalogued as rs759002690; called by mutect2, pindel, varscan2
- INPP4A | c.2014T>C p.Y672H (on ENST00000074304 / NM_001134224.1; = p.Y633H on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.929); catalogued as rs1372591736; called by muse, mutect2
- INPP4A | c.2318C>T p.P773L (on ENST00000074304 / NM_001134224.1; = p.P734L on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/313 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223323677; called by muse, mutect2, varscan2
- IQCG | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs779301526; called by muse, mutect2, varscan2
- IRX1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 117/427 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs552213084, COSV57360141, COSV57362250; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs747772781, COSV56440200; called by muse, mutect2, varscan2
- ITGA3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as rs766249771, COSV99143639; called by muse, mutect2, varscan2
- ITGA6 | c.3110G>A p.R1037Q (on ENST00000442250; = p.R998Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as rs1373015067; called by muse, mutect2, varscan2
- ITGA7 | c.3541G>A p.A1181T (on ENST00000555728; = p.A1137T on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/432 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs772419744, COSV57693371; called by muse, mutect2, varscan2
- ITGAX | c.3404G>A p.R1135H | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375617767; called by muse, mutect2, varscan2
- JADE2 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 33/495 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs115812370; called by muse, mutect2
- KANK1 | c.3373G>A p.V1125M | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148400033; called by muse, mutect2, varscan2
- KBTBD6 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 91/388 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs756607623, COSV65271899; called by muse, mutect2, varscan2
- KBTBD7 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 102/405 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as rs773202669, COSV101068062; called by muse, mutect2, varscan2
- KCNAB1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV67490069; called by muse, mutect2, varscan2
- KCNC1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 116/429 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV99789377; called by muse, varscan2
- KCND1 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 22/508 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371441000, COSV99501957; called by muse, mutect2
- KCNF1 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs751488924; called by muse, mutect2, varscan2
- KCNK4 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 40/542 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs754106221; called by muse, mutect2
- KCNK4 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 156/647 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100107779; called by muse, varscan2
- KCNN1 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1351577896; called by muse, mutect2, varscan2
- KCTD3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs933938609; called by muse, mutect2, varscan2
- KIAA0232 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1188142882, COSV100301063; called by muse, mutect2, varscan2
- KIAA1549L | c.1884G>A p.A628= (on ENST00000321505; = p.A925= on NM_012194.3) | Splice Region (SNP) | VAF 65/194 reads (34%) | catalogued as rs770364632; called by muse, mutect2, varscan2
- KIF13A | c.3345dup p.V1116Sfs*4 | Frame Shift Ins (INS) | VAF 35/211 reads (17%) | catalogued as rs1346755993; called by mutect2, varscan2
- KIF16B | c.2246del p.K749Rfs*3 | Frame Shift Del (DEL) | VAF 70/272 reads (26%) | catalogued as rs35229389; called by mutect2, varscan2
- KIF21B | c.1010del p.G337Afs*7 | Frame Shift Del (DEL) | VAF 38/190 reads (20%) | catalogued as rs778434242, COSV59766546; called by mutect2, pindel, varscan2
- KLF16 | c.290del p.G97Afs*48 | Frame Shift Del (DEL) | VAF 51/222 reads (23%) | catalogued as rs1413895006; called by mutect2, pindel, varscan2
- KLHL3 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 107/412 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139384947; called by muse, mutect2
- KLHL34 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 115/548 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV101069961; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1403628021; called by muse, mutect2, varscan2
- KNDC1 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs564903874; called by muse, mutect2, varscan2
- KRT2 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 113/420 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs376889647; called by muse, mutect2, varscan2
- KRT73 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV59838486; called by muse, mutect2, varscan2
- KRT86 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 147/609 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs754153541, COSV53293919; called by muse, mutect2, varscan2
- L1CAM | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 101/558 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs200605257, COSV62828942; called by muse, mutect2, varscan2
- L3MBTL2 | c.600C>T p.H200= | Splice Region (SNP) | VAF 49/216 reads (23%) | catalogued as rs779290651; called by muse, mutect2, varscan2
- LAMA2 | c.3372del p.K1124Nfs*15 | Frame Shift Del (DEL) | VAF 73/299 reads (24%) | catalogued as rs1361925574, COSV70347760; called by mutect2, pindel, varscan2
- LAMA2 | c.4683G>T p.K1561N | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs1263027224; called by muse, mutect2, varscan2
- LAMA4 | c.2667+1G>A p.X889_splice (on ENST00000230538 / NM_001105206.3; = p.X882_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 45/170 reads (26%) | catalogued as rs1373538377; called by muse, mutect2, varscan2
- LAMA5 | c.4072G>A p.E1358K | Missense Mutation (SNP) | VAF 139/486 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs757478552; called by muse, mutect2, varscan2
- LAMB1 | c.5100del p.V1701* | Frame Shift Del (DEL) | VAF 38/187 reads (20%) | catalogued as COSV99227225; called by mutect2, pindel, varscan2
- LAMC1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51132524, COSV99278997; called by muse, mutect2
- LCAT | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs769067928; called by muse, mutect2, varscan2
- LCOR | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs1437417674, COSV63629881; called by muse, mutect2, varscan2
- LGALS4 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760505571, COSV57044049; called by muse, mutect2
- LGI3 | c.26del p.G9Afs*61 | Frame Shift Del (DEL) | VAF 24/170 reads (14%) | catalogued as rs894404355; called by mutect2, varscan2
- LIPE | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 24/529 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1459680120; called by muse, mutect2
- LKAAEAR1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 168/589 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs745746996; called by muse, mutect2, varscan2
- LMTK3 | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1404107935; called by muse, varscan2
- LRCH1 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV60851562; called by muse, mutect2
- LRCH2 | c.1055A>G p.D352G | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57747503; called by muse, mutect2, varscan2
- LRP1 | c.6541G>A p.A2181T | Missense Mutation (SNP) | VAF 135/441 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs377241209; called by muse, mutect2, varscan2
- LRP1B | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs772492671; called by muse, mutect2, varscan2
- LRP2 | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368997664; called by muse, mutect2
- LRRC17 | c.1272dup p.H425Tfs*2 | Frame Shift Ins (INS) | VAF 64/322 reads (20%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC43 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 93/384 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.38); catalogued as rs368344594; called by muse, varscan2
- LRRFIP1 | c.2278G>A p.V760I (on ENST00000392000 / NM_001137552.2; = p.V736I on NM_004735.4) | Missense Mutation (SNP) | VAF 118/429 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs763673830; called by muse, mutect2, varscan2
- LRTOMT | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as rs374233636; called by muse, mutect2, varscan2
- LY75-CD302 | c.5508del p.K1836Nfs*26 | Frame Shift Del (DEL) | VAF 58/266 reads (22%) | catalogued as rs769756355; called by mutect2, pindel, varscan2
- MAGEC1 | c.3371C>T p.S1124L | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as rs747835069, COSV53576803, COSV53580170; called by muse, varscan2
- MAGEE1 | c.2414T>G p.L805R | Missense Mutation (SNP) | VAF 78/414 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63908813, COSV63909025; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 69/258 reads (27%) | catalogued as rs752869239; called by mutect2, varscan2
- MAP3K9 | c.3257C>T p.A1086V (on ENST00000554752 / NM_001284230.1; = p.A1100V on NM_033141.4) | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs776047235, COSV67121634; called by muse, mutect2, varscan2
- MAPK8IP2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 112/422 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1217305719; called by mutect2, varscan2
- MAST3 | c.3143G>T p.R1048L | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99444458; called by muse, varscan2
- MAU2 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1382252849, COSV53234386; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | catalogued as rs762648935; called by mutect2, pindel, varscan2
- MCPH1 | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV60916074; called by muse, mutect2, varscan2
- MIEF2 | c.698G>A p.C233Y | Missense Mutation (SNP) | VAF 130/521 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs781021060; called by muse, mutect2, varscan2
- MMACHC | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 92/403 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs201777449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MNDA | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 133/407 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV63741842, COSV63742414; called by mutect2, varscan2
- MSR1 | c.694_696del p.E232del | In Frame Del (DEL) | VAF 49/248 reads (20%) | catalogued as rs1187006037; called by pindel, varscan2
- MTARC2 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs746721056; called by muse, mutect2, varscan2
- MUC16 | c.8903C>A p.P2968H | Missense Mutation (SNP) | VAF 88/356 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as rs761976138, COSV67455578; called by muse, mutect2, varscan2
- MUC2 | c.4009G>A p.E1337K | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs754330813; called by muse, mutect2, varscan2
- MUC6 | c.1622C>T p.T541M | Missense Mutation (SNP) | VAF 110/476 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs753925522, COSV70140021; called by muse, mutect2, varscan2
- MYH10 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs1358481726; called by muse, varscan2
- MYH10 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs747662974; called by muse, mutect2, varscan2
- MYH13 | c.1169T>C p.M390T | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV52832181; called by muse, mutect2, varscan2
- MYH9 | c.5293G>A p.D1765N | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs779971012, COSV53393135; called by muse, mutect2, varscan2
- MYO1F | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs368617557; called by muse, mutect2, varscan2
- MYO7B | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs866178227, COSV67347469; called by muse, mutect2
- MYOC | c.1178G>T p.S393I | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023430; called by muse, mutect2, varscan2
- NARS1 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs776234547, COSV56877976; called by muse, mutect2, varscan2
- NAV1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 113/486 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs894248875; called by muse, varscan2
- NBEAL2 | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 125/472 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs373890544; called by muse, mutect2, varscan2
- NCOA6 | c.1997del p.P666Rfs*12 | Frame Shift Del (DEL) | VAF 89/478 reads (19%) | catalogued as rs763811545; called by mutect2, pindel, varscan2
- NECTIN1 | c.1219del p.Q407Sfs*191 | Frame Shift Del (DEL) | VAF 113/444 reads (25%) | catalogued as COSV50605488; called by mutect2, pindel, varscan2
- NEK11 | c.406_408del p.I136del | In Frame Del (DEL) | VAF 32/180 reads (18%) | catalogued as rs1384676789; called by pindel, varscan2
- NELL2 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs758122258, COSV61588124; called by muse, mutect2, varscan2
- NEU2 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 120/548 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV52091532; called by muse, varscan2
- NEXN | c.828_830del p.E277del | In Frame Del (DEL) | VAF 66/254 reads (26%) | catalogued as rs750308076; called by pindel, varscan2
- NF1 | c.2770G>T p.E924* | Nonsense Mutation (SNP) | VAF 82/293 reads (28%) | catalogued as COSV62224906; called by muse, mutect2, varscan2
- NGEF | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 69/335 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1309453054; called by muse, mutect2, varscan2
- NKX1-1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV70026178, COSV70026257; called by muse, mutect2, varscan2
- NKX1-1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT deleterious, low confidence (0.01); catalogued as rs980489640, COSV70026235; called by muse, mutect2, varscan2
- NLGN2 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 98/438 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56658326; called by muse, mutect2, varscan2
- NLRP10 | c.1250C>A p.A417E | Missense Mutation (SNP) | VAF 143/482 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1468654786, COSV60779214; called by muse, mutect2, varscan2
- NLRP11 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 86/328 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs141337326; called by muse, varscan2
- NOTCH1 | c.3985G>A p.A1329T | Missense Mutation (SNP) | VAF 102/372 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as rs763098618; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD2 | c.2523del p.X841_splice | Splice Site (DEL) | VAF 70/210 reads (33%) | catalogued as COSV100373568; called by mutect2, pindel, varscan2
- NSDHL | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 243/564 reads (43%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.899); catalogued as rs782143078, COSV64743539; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NSMAF | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 78/370 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs147647770; called by muse, varscan2
- NT5DC2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs573448959, COSV58732672; called by muse, mutect2, varscan2
- NT5DC3 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67322659; called by muse, mutect2, varscan2
- NUP107 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs768676886, COSV57494561; called by muse, mutect2, varscan2
- NUP205 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV53663998; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 42/211 reads (20%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NUP98 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs201706881, COSV61434709; called by muse, mutect2, varscan2
- NXNL1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 91/429 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as rs779760677; called by muse, mutect2, varscan2
- OCA2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs151118268; called by muse, varscan2
- OOSP1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1014942459; called by muse, mutect2, varscan2
- OR10AG1 | c.67T>G p.L23V | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV56633199; called by muse, mutect2, varscan2
- OR2T6 | c.573C>A p.D191E | Missense Mutation (SNP) | VAF 133/579 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs753889841; called by muse, mutect2, varscan2
- OR56A1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs145606510; called by muse, mutect2, varscan2
- OR5D3P | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 86/345 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1230572207; called by muse, mutect2, varscan2
- OSBPL5 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457825257, COSV55140682; called by muse, mutect2, varscan2
- OSBPL6 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 48/259 reads (19%) | catalogued as rs1559319934, COSV99507163; called by muse, mutect2, varscan2
- OSR1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 122/500 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.329); catalogued as rs947794638; called by muse, mutect2, varscan2
- OTOP2 | c.958C>A p.R320S | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as rs767497383, COSV58883679; called by muse, mutect2, varscan2
- P2RY2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 119/442 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs751836374, COSV60776807; called by muse, mutect2, varscan2
- PABPC1L | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 99/368 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as rs761790341, COSV104369771; called by muse, mutect2, varscan2
- PAMR1 | c.302dup p.T102Yfs*4 | Frame Shift Ins (INS) | VAF 53/283 reads (19%) | catalogued as rs751755759; called by mutect2, varscan2
- PANK4 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs764274059; called by muse, varscan2
- PANX2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 140/660 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1160790229, COSV50299490; called by muse, mutect2, varscan2
- PAPOLA | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 26/152 reads (17%) | catalogued as COSV99354262; called by muse, mutect2, varscan2
- PAPPA | c.3044C>T p.T1015M | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746134475, COSV60288614; called by muse, mutect2, varscan2
- PAPPA2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 113/335 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as rs749736695; called by muse, mutect2, varscan2
- PAPPA2 | c.1911C>G p.N637K | Missense Mutation (SNP) | VAF 75/349 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.201); catalogued as COSV62774391; called by muse, mutect2, varscan2
- PAPPA2 | c.4516C>A p.L1506M | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62813410; called by muse, mutect2, varscan2
- PARP10 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 68/398 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1324384713; called by muse, mutect2, varscan2
- PASK | c.3065del p.N1022Tfs*6 | Frame Shift Del (DEL) | VAF 27/159 reads (17%) | catalogued as rs745388191; called by mutect2, pindel, varscan2
- PCCA | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs755120963, COSV66195510; called by muse, mutect2, varscan2
- PCDH10 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 121/447 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52095609, COSV52099314; called by muse, mutect2, varscan2
- PCDH19 | c.3077C>T p.P1026L (on ENST00000373034 / NM_001184880.2; = p.P978L on NM_020766.3) | Missense Mutation (SNP) | VAF 124/484 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs762888017, COSV55259749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA3 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 92/406 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as rs896701889, COSV65372057; called by muse, mutect2, varscan2
- PCDHA7 | c.1948C>A p.L650I | Missense Mutation (SNP) | VAF 71/337 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as rs1554135818; called by muse, mutect2, varscan2
- PCDHB10 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 99/594 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs781965062; called by muse, mutect2, varscan2
- PCDHGB4 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs748559328, COSV53895525; called by muse, mutect2, varscan2
- PDE9A | c.683del p.L228Wfs*7 | Frame Shift Del (DEL) | VAF 20/236 reads (8%) | catalogued as rs1216905628; called by mutect2, pindel
- PDZD2 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 94/373 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763929150, COSV56851617; called by muse, mutect2, varscan2
- PGAP6 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs374799437; called by muse, mutect2, varscan2
- PGGHG | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as rs114112322; called by muse, mutect2, varscan2
- PGM2 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781317423; called by muse, mutect2, varscan2
- PHKA2 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs188998010; called by muse, mutect2, varscan2
- PHLPP2 | c.3905G>A p.R1302Q | Missense Mutation (SNP) | VAF 106/429 reads (25%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.267); catalogued as rs192113290; called by muse, mutect2, varscan2
- PIBF1 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147185245; called by muse, mutect2, varscan2
- PIP4P2 | c.538del p.I180Sfs*21 | Frame Shift Del (DEL) | VAF 39/188 reads (21%) | catalogued as rs1158949501; called by mutect2, pindel, varscan2
- PITPNM3 | c.2548G>A p.V850M | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs558698054; called by muse, mutect2, varscan2
- PITPNM3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 106/418 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as rs200418753; called by muse, mutect2, varscan2
- PKD1 | c.6497G>A p.R2166H | Missense Mutation (SNP) | VAF 111/479 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs754882717, COSV99238744; called by muse, mutect2, varscan2
- PKP4 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 93/366 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.913); catalogued as COSV61580984; called by muse, varscan2
- PLA2G6 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451486649; called by muse, mutect2, varscan2
- PLCH2 | c.3181G>A p.G1061S | Missense Mutation (SNP) | VAF 144/608 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as rs1291770917; called by muse, varscan2
- PLEC | c.11261G>A p.R3754H (on ENST00000322810 / NM_201380.4; = p.R3644H on NM_000445.5) | Missense Mutation (SNP) | VAF 94/529 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs782758161, COSV59619696; called by muse, varscan2
- PLEKHF1 | c.244del p.L82Wfs*20 | Frame Shift Del (DEL) | VAF 100/445 reads (22%) | catalogued as COSV101460749; called by mutect2, pindel, varscan2
- PLEKHG2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 90/376 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1053602472; called by muse, mutect2, varscan2
- PLEKHG4B | c.1337G>T p.R446M (on ENST00000283426; = p.R802M on NM_052909.5) | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV52047528, COSV52049872, COSV99361528; called by muse, mutect2, varscan2
- PLIN3 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749047424, COSV55734845; called by muse, varscan2
- PLXNA1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs139335831; called by muse, mutect2, varscan2
- PLXNA2 | c.3652G>A p.G1218R | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374725426, COSV100885286; called by muse, mutect2, varscan2
- PNKD | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs759669801, COSV51230865; ClinVar: likely benign; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1294T>A p.L432M | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV65047669; called by muse, mutect2, varscan2
- PNMA8B | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 105/472 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV66536232; called by muse, mutect2, varscan2
- PODN | c.1457C>T p.S486L (on ENST00000395871; = p.S438L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/594 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1557656592, COSV57014967; called by muse, mutect2
- POLD3 | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99737569; called by muse, mutect2, varscan2
- POLE | c.4454G>A p.R1485H | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs973405989, COSV57675329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR1A | c.3451C>T p.R1151C | Missense Mutation (SNP) | VAF 55/324 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777005760; called by muse, varscan2
- POLR2C | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV54671700; called by muse, mutect2, varscan2
- POMC | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 116/493 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as COSV53034290; called by muse, mutect2, varscan2
- POMZP3 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 128/540 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as rs762361424, COSV99300631; called by muse, mutect2, varscan2
- POU3F1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as rs1303710468; called by mutect2, varscan2
- PPFIA2 | c.3215C>A p.T1072K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs759626200; called by mutect2, varscan2
- PPID | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs201748429; called by muse, mutect2, varscan2
- PPM1N | c.738del p.E247Sfs*73 | Frame Shift Del (DEL) | VAF 68/398 reads (17%) | catalogued as COSV99838951; called by mutect2, pindel, varscan2
- PPP1R16A | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 82/457 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs535844929; called by muse, mutect2, varscan2
- PPP1R3A | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); catalogued as rs754146113; called by muse, mutect2, varscan2
- PPRC1 | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 114/383 reads (30%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs752744120; called by muse, mutect2, varscan2
- PRAM1 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 125/446 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750535341, COSV99725290; called by muse, mutect2, varscan2
- PRG3 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1450898460; called by muse, mutect2, varscan2
- PRKD2 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs763806572, COSV52190887; called by muse, mutect2, varscan2
- PRMT7 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 85/444 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371698853; called by muse, mutect2, varscan2
- PRPF6 | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1297870965, COSV53866849; called by muse, mutect2, varscan2
- PRR23B | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 134/521 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs769761624; called by muse, mutect2, varscan2
- PRRT4 | c.2431C>T p.R811W | Missense Mutation (SNP) | VAF 139/547 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV71055135; called by muse, mutect2, varscan2
- PSMC4 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1568377136, COSV50095696; called by muse, mutect2
- PSRC1 | c.794G>A p.R265Q (on ENST00000409138 / NM_001363309.1; = p.R235Q on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs201288741; called by muse, mutect2, varscan2
- PTPRB | c.4064C>A p.P1355H | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54237868; called by muse, mutect2, varscan2
- PUM3 | c.1023del p.K342Nfs*6 | Frame Shift Del (DEL) | VAF 34/196 reads (17%) | catalogued as rs749329036; called by mutect2, pindel, varscan2
- PUS10 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 61/325 reads (19%) | catalogued as rs371157664; called by muse, mutect2, varscan2
- PXMP2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs773878799; called by muse, mutect2, varscan2
- QRICH2 | c.4235C>T p.A1412V | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs751887084, COSV53152842; called by muse, mutect2, varscan2
- RAN | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 20/423 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV54563712; called by muse, mutect2
- RANBP2 | c.3613G>A p.D1205N | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936822747, COSV51701240, COSV51706647; called by muse, mutect2, varscan2
- RBFOX1 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV60945427; called by muse, mutect2, varscan2
- RBM45 | c.722G>A p.R241Q (on ENST00000616198 / NM_001365579.1; = p.R239Q on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.86); catalogued as rs750456960, COSV53722987; called by muse, mutect2, varscan2
- RDH5 | c.718del p.A240Pfs*7 | Frame Shift Del (DEL) | VAF 54/250 reads (22%) | catalogued as rs753378940, CM991095; called by mutect2, pindel, varscan2
- RDH8 | c.985C>T p.R329W (on ENST00000651512; = p.R309W on NM_015725.4) | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs779676963, COSV99408686; called by muse, mutect2, varscan2
- RELN | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as COSV100633949; called by muse, mutect2, varscan2
- REPS2 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754563907; called by muse, mutect2, varscan2
- RGPD4 | c.5108A>G p.Q1703R | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs747755931; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 38/146 reads (26%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RHBDL3 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 102/330 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778891200; called by muse, mutect2, varscan2
- RHOBTB1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs201499193; called by muse, mutect2, varscan2
- RHOBTB2 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 86/413 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs745317492, COSV52571111; called by muse, mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 40/184 reads (22%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RNF146 | c.485G>A p.R162H (on ENST00000368314 / NM_001242850.2; = p.R161H on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420065912, COSV58931295; called by muse, mutect2, varscan2
- RNF150 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV100152961; called by muse, mutect2, varscan2
- RNF165 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 99/481 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.995); catalogued as rs1568039911; called by muse, mutect2, varscan2
- RNF208 | c.724T>C p.Y242H | Missense Mutation (SNP) | VAF 103/444 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as rs1287989402; called by muse, mutect2, varscan2
- ROR2 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.604); catalogued as rs1399289486; called by muse, mutect2, varscan2
- RPE65 | c.992G>A p.W331* | Nonsense Mutation (SNP) | VAF 52/207 reads (25%) | catalogued as rs761471961, CM155747; called by muse, mutect2, varscan2
- RPGRIP1L | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs202124667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPN2 | c.1031G>C p.G344A | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772699247, COSV52908070; called by muse, mutect2, varscan2
- RPP40 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 120/429 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs558469947; called by muse, mutect2, varscan2
- RPS6KA6 | c.327del p.A110Pfs*3 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | catalogued as rs756096568; called by mutect2, pindel, varscan2
- RRP1B | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342574440, COSV61478465; called by muse, varscan2
- RTL8C | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 72/351 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV57059908; called by muse, mutect2, varscan2
- RTTN | c.5962C>T p.L1988F | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs769662761; called by muse, mutect2, varscan2
- RTTN | c.3824C>T p.A1275V | Missense Mutation (SNP) | VAF 97/349 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as rs368042408; called by muse, mutect2, varscan2
- RXFP2 | c.1067A>G p.Q356R | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1246634694; called by muse, mutect2, varscan2
- S1PR1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 146/502 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59512947; called by muse, mutect2, varscan2
- SBF1 | c.4769C>T p.T1590M | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs371896005; called by muse, mutect2, varscan2
- SCARA3 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770196500; called by muse, mutect2, varscan2
- SCUBE3 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750286127, COSV51458175; called by muse, mutect2, varscan2
- SDF4 | c.611del p.P204Lfs*6 | Frame Shift Del (DEL) | VAF 84/377 reads (22%) | catalogued as COSV55419193; called by mutect2, pindel, varscan2
- SDK1 | c.6580G>A p.V2194I | Missense Mutation (SNP) | VAF 83/438 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.314); catalogued as rs767392707; called by muse, mutect2, varscan2
- SEC16A | c.1689del p.F563Lfs*9 | Frame Shift Del (DEL) | VAF 64/298 reads (21%) | catalogued as COSV99255876; called by mutect2, varscan2
- SEL1L2 | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.932); catalogued as rs1199863544; called by muse, mutect2, varscan2
- SEMA4G | c.236_237del p.L79Qfs*38 | Frame Shift Del (DEL) | VAF 70/368 reads (19%) | catalogued as rs1441071018; called by pindel, varscan2
- SENP3 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 79/368 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1230589519, COSV53437577; called by muse, varscan2
- SERINC2 | c.538G>A p.D180N (on ENST00000373709 / NM_178865.5; = p.D184N on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1286546991; called by muse, mutect2, varscan2
- SERPINB7 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs150173362; called by muse, mutect2, varscan2
- SETD5 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 110/433 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775813972; called by muse, mutect2, varscan2
- SFI1 | c.2261T>C p.L754P (on ENST00000400288 / NM_001007467.3; = p.L723P on NM_014775.4) | Missense Mutation (SNP) | VAF 75/363 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63476016; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 58/229 reads (25%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SH3RF3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 93/362 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as rs1005743454; called by muse, mutect2, varscan2
- SH3RF3 | c.2038G>A p.V680I | Missense Mutation (SNP) | VAF 102/461 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.362); catalogued as rs769483783; called by muse, mutect2, varscan2
- SH3TC1 | c.3283-1G>T p.X1095_splice | Splice Site (SNP) | VAF 59/197 reads (30%) | catalogued as rs756879467; called by muse, mutect2, varscan2
- SHANK1 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 94/383 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1208223493, COSV53258652; called by muse, mutect2, varscan2
- SHFL | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 79/403 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs944898044, COSV53461652; called by muse, mutect2, varscan2
- SHISAL1 | c.506del p.P169Qfs*23 | Frame Shift Del (DEL) | VAF 86/407 reads (21%) | catalogued as rs1569218027; called by mutect2, pindel, varscan2
- SHOX | c.728del p.P243Rfs*164 | Frame Shift Del (DEL) | VAF 94/433 reads (22%) | catalogued as rs757845999, COSV61860885; called by mutect2, pindel, varscan2
- SIGLEC7 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs376908794; called by muse, mutect2, varscan2
- SIPA1L2 | c.4106A>G p.Y1369C | Missense Mutation (SNP) | VAF 72/267 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.936); catalogued as rs756573973; called by muse, mutect2, varscan2
- SIRPB1 | c.838del p.R280Gfs*5 | Frame Shift Del (DEL) | VAF 58/319 reads (18%) | catalogued as COSV99498551; called by mutect2, pindel, varscan2
- SLC15A2 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as rs771680786, COSV55200336; called by muse, mutect2, varscan2
- SLC24A5 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs1235896523; called by muse, mutect2
- SLC45A4 | c.2398del p.I800Ffs*53 (on ENST00000517878 / NM_001286646.2; = p.K746Nfs*13 on NM_001080431.2) | Frame Shift Del (DEL) | VAF 58/282 reads (21%) | catalogued as rs765323954, COSV99198528; called by mutect2, varscan2
- SLC5A2 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 105/412 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs761139723, COSV57890504, COSV57892575; called by muse, mutect2, varscan2
- SLC9A4 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 93/363 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.078); catalogued as rs562401734, COSV54832192; called by muse, mutect2, varscan2
- SLCO1C1 | c.358G>T p.G120* | Nonsense Mutation (SNP) | VAF 54/273 reads (20%) | catalogued as COSV99860216; called by mutect2, varscan2
- SMG1 | c.5866C>T p.R1956C | Missense Mutation (SNP) | VAF 75/319 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs755564591; called by muse, mutect2, varscan2
- SNAI1 | c.309del p.S104Afs*176 | Frame Shift Del (DEL) | VAF 53/342 reads (15%) | catalogued as COSV54865122; called by mutect2, varscan2
- SNRNP200 | c.3805C>T p.R1269* | Nonsense Mutation (SNP) | VAF 79/294 reads (27%) | catalogued as rs971963321, COSV60487723, COSV60493375; called by muse, mutect2, varscan2
- SNTA1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs150474420; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 58/166 reads (35%) | catalogued as rs768873484; called by mutect2, varscan2
- SOGA1 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 134/503 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1416488795; called by muse, mutect2, varscan2
- SORCS1 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 90/405 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.134); catalogued as COSV53890482, COSV99548516; called by muse, mutect2, varscan2
- SP6 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 83/396 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs982594079; called by muse, mutect2, varscan2
- SPARC | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 96/404 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.323); catalogued as rs776630906; called by muse, varscan2
- SPNS3 | c.1382del p.G461Afs*6 | Frame Shift Del (DEL) | VAF 74/385 reads (19%) | catalogued as rs756918252; called by pindel, varscan2
- SPOCD1 | c.1485del p.Q496Sfs*9 | Frame Shift Del (DEL) | VAF 73/337 reads (22%) | catalogued as rs780220675; called by mutect2, pindel, varscan2
- SPON1 | c.498del p.K166Nfs*12 | Frame Shift Del (DEL) | VAF 44/191 reads (23%) | catalogued as COSV100115041; called by mutect2, pindel, varscan2
- SPTBN4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212063873, COSV58943610; called by muse, mutect2, varscan2
- SRRM2 | c.5165del p.P1722Qfs*161 | Frame Shift Del (DEL) | VAF 82/400 reads (21%) | catalogued as rs1567237631, COSV57072330; called by mutect2, pindel, varscan2
- SSBP4 | c.378del p.G127Afs*13 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as rs760883618; called by mutect2, pindel, varscan2
- ST6GALNAC4 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 126/517 reads (24%) | PolyPhen probably damaging (1); catalogued as rs759949151; called by muse, mutect2, varscan2
- SYNPO | c.2345G>A p.R782Q (on ENST00000394243 / NM_001166208.2; = p.R538Q on NM_007286.6) | Missense Mutation (SNP) | VAF 114/501 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as rs368637681; called by muse, mutect2, varscan2
- TAAR9 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 105/379 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs199962808, COSV71512249; called by muse, mutect2, varscan2
- TAF1D | c.483dup p.N162* | Frame Shift Ins (INS) | VAF 39/156 reads (25%) | catalogued as rs1306502405; called by mutect2, pindel, varscan2
- TAF4 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 119/530 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs754503916; called by muse, mutect2, varscan2
- TAF7 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57665690; called by muse, mutect2, varscan2
- TANC1 | c.3827C>T p.A1276V | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs749103357, COSV55084044; called by muse, mutect2, varscan2
- TAS2R14 | c.567A>G p.I189M | Missense Mutation (SNP) | VAF 89/397 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1157023586, COSV67852234; called by muse, mutect2, varscan2
- TATDN3 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs781256061; called by muse, mutect2, varscan2
- TBX10 | c.291del p.F98Sfs*3 | Frame Shift Del (DEL) | VAF 58/384 reads (15%) | catalogued as rs748952707, COSV56876494; called by mutect2, pindel, varscan2
- TCHH | c.5195G>A p.R1732H | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.912); catalogued as rs768857593; called by muse, mutect2, varscan2
- TCTEX1D4 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 137/551 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1362806633; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 46/249 reads (18%) | catalogued as rs763321097; called by mutect2, varscan2
- TEDC1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs983489160; called by muse, mutect2
- TEF | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56747913; called by muse, mutect2, varscan2
- TENM2 | c.4354C>T p.R1452C (on ENST00000518659 / NM_001122679.2; = p.R1213C on NM_001080428.3) | Missense Mutation (SNP) | VAF 105/445 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749316450, COSV69123826; called by muse, mutect2, varscan2
- TENM4 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 126/531 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs751467112, COSV99579163; called by muse, mutect2, varscan2
- TENT4A | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 113/454 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs771321599; called by muse, mutect2, varscan2
- TESK2 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs200465813; called by muse, mutect2, varscan2
- TET2 | c.4964C>T p.P1655L | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs372419310, COSV99036216; called by muse, varscan2
- TFE3 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV59947567; called by muse, mutect2, varscan2
- TGFBR3 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 55/217 reads (25%) | catalogued as COSV53022699; called by muse, mutect2, varscan2
- THBS3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 79/359 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs759137845, COSV100857649; called by muse, mutect2, varscan2
- TJP2 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 133/548 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.745); catalogued as rs1231714929; called by muse, mutect2, varscan2
- TLL1 | c.1290A>C p.E430D | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV50263319; called by muse, mutect2, varscan2
- TLR9 | c.1315del p.E439Rfs*47 | Frame Shift Del (DEL) | VAF 95/430 reads (22%) | catalogued as rs1223235663; called by mutect2, pindel, varscan2
- TMEM100 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 80/368 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs781293521, COSV70118016; called by muse, mutect2, varscan2
- TMEM132A | c.1889C>T p.T630M (on ENST00000453848 / NM_178031.3; = p.T631M on NM_017870.4) | Missense Mutation (SNP) | VAF 93/360 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs763174302, COSV99133752; called by muse, varscan2
- TMEM221 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 119/445 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs978326775; called by muse, mutect2, varscan2
- TMEM240 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs930200585; called by muse, mutect2, varscan2
- TMEM37 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs780577316, COSV50026854; called by muse, mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 165/359 reads (46%) | catalogued as rs747222326; called by mutect2, pindel, varscan2
- TMPRSS9 | c.1352G>A p.R451H (on ENST00000648592; = p.R417H on NM_182973.2) | Missense Mutation (SNP) | VAF 135/460 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs145109209; called by muse, mutect2, varscan2
- TNC | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 84/385 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs764927501, COSV60784030; called by muse, mutect2, varscan2
- TNPO1 | c.2530del p.C844Vfs*45 | Frame Shift Del (DEL) | VAF 34/150 reads (23%) | catalogued as rs757314136; called by mutect2, pindel, varscan2
- TNRC18 | c.7564G>A p.D2522N | Missense Mutation (SNP) | VAF 129/464 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs764918789; called by muse, mutect2, varscan2
- TNRC18 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 150/589 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1234135097; called by muse, varscan2
- TNS3 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780395262; called by muse, varscan2
- TOGARAM2 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65421349; called by muse, mutect2, varscan2
- TOP1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs957960003, COSV100794000; called by muse, varscan2
- TPBG | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 100/454 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1236898164; called by muse, mutect2, varscan2
- TPST1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 89/413 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs375955079, COSV104395918; called by muse, mutect2, varscan2
- TRAF7 | c.46C>G p.P16A | Missense Mutation (SNP) | VAF 105/382 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1188110300, COSV100399532; called by muse, mutect2, varscan2
- TRHDE | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 138/535 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.116); catalogued as rs1328262380; called by muse, mutect2, varscan2
- TRIM58 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 126/510 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753804289, COSV63569130; called by muse, mutect2, varscan2
- TSPOAP1 | c.2807G>A p.R936Q | Missense Mutation (SNP) | VAF 151/567 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as rs377765738; called by muse, mutect2, varscan2
- TTC22 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 124/536 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1164006901; called by muse, varscan2
- TTC3 | c.4692del p.E1565Kfs*6 | Frame Shift Del (DEL) | VAF 23/123 reads (19%) | catalogued as rs778730652; called by mutect2, varscan2
- TTN | c.82709G>A p.R27570H (on ENST00000591111; = p.R20146H on NM_003319.4) | Missense Mutation (SNP) | VAF 72/381 reads (19%) | PolyPhen probably damaging (0.998); catalogued as rs370948914, COSV60120952; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTYH3 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 110/417 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763512894; called by muse, mutect2, varscan2
- TUBB8B | c.724T>A p.F242I | Missense Mutation (SNP) | VAF 96/1024 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs772290413; called by muse, varscan2
- ULK1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1015290249; called by muse, mutect2, varscan2
- UNC79 | c.1315G>A p.A439T (on ENST00000393151 / NM_001346218.2; = p.A262T on NM_020818.5) | Missense Mutation (SNP) | VAF 84/426 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs199853805, COSV56382871; called by muse, mutect2, varscan2
- UNC80 | c.9221G>A p.R3074H | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.579); catalogued as rs1413695148; called by muse, mutect2, varscan2
- USP20 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777767168, COSV100205134; called by muse, mutect2
- VAT1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 144/514 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs758303820; called by muse, mutect2, varscan2
- VAX1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1176473736; called by muse, mutect2, varscan2
- VENTX | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs367704244; called by muse, mutect2, varscan2
- VEZT | c.220del p.S74Lfs*38 | Frame Shift Del (DEL) | VAF 32/196 reads (16%) | catalogued as rs748321397; called by mutect2, varscan2
- VILL | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 73/350 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs372162890; called by muse, mutect2, varscan2
- VLDLR | c.2459G>A p.R820Q | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775603429, COSV66077667; called by muse, mutect2, varscan2
- VPS13A | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.08); catalogued as rs146896963; called by muse, varscan2
- VPS13D | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs757652596, COSV100692688; called by muse, mutect2, varscan2
- VPS13D | c.6466G>A p.V2156I | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368253297; called by muse, mutect2, varscan2
- VWA5B2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 134/419 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1402875552; called by muse, varscan2
- VWCE | c.2851del p.E951Kfs*33 | Frame Shift Del (DEL) | VAF 80/341 reads (23%) | catalogued as rs770073614, COSV57111238; called by mutect2, pindel, varscan2
- WASHC2C | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs782376645; called by muse, mutect2, varscan2
- WDR86 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1402170029; called by muse, varscan2
- WHRN | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 120/510 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.046); catalogued as COSV54332719; called by muse, varscan2
- WHRN | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 123/464 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs918856387; called by muse, varscan2
- WHRN | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 100/401 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs760261757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNT11 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 103/389 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs780236055; called by muse, mutect2, varscan2
- WNT2B | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 89/394 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV56672500; called by muse, mutect2
- XIRP2 | c.1438C>T p.R480W (on ENST00000628543; = p.R655W on NM_152381.6) | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs778966902; called by muse, mutect2, varscan2
- XIRP2 | c.6796del p.S2266Pfs*26 (on ENST00000628543; = p.S2441Pfs*26 on NM_152381.6) | Frame Shift Del (DEL) | VAF 77/335 reads (23%) | catalogued as rs768866622, COSV54687798, COSV54690039; called by mutect2, pindel, varscan2
- XYLT2 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 119/472 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs752138305; called by muse, mutect2, varscan2
- ZAR1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1560482108; called by muse, varscan2
- ZBED2 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 88/371 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.188); catalogued as rs759352888, COSV51914734; called by muse, mutect2, varscan2
- ZBTB10 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770816266; called by muse, mutect2, varscan2
- ZC3H11B | c.865T>G p.F289V | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1393964805; called by muse, mutect2, varscan2
- ZC3H7A | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs746259386; called by muse, mutect2, varscan2
- ZFHX4 | c.342C>A p.S114R | Missense Mutation (SNP) | VAF 67/371 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV51497654, COSV99260630; called by muse, mutect2, varscan2
- ZFHX4 | c.3946G>T p.G1316W | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV51497798; called by muse, mutect2, varscan2
- ZG16 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 67/301 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as rs924075061, COSV68783881; called by muse, mutect2, varscan2
- ZNF10 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.703); catalogued as rs1486313265, COSV50212199; called by muse, mutect2, varscan2
- ZNF208 | c.2734A>G p.T912A | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1444964686; called by muse, mutect2
- ZNF274 | c.892C>T p.R298W (on ENST00000610905; = p.R193W on NM_016324.3) | Missense Mutation (SNP) | VAF 85/342 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.828); catalogued as rs764561877; called by muse, mutect2, varscan2
- ZNF469 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 150/554 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs759962057, COSV104436363; called by muse, mutect2, varscan2
- ZNF469 | c.2779C>T p.R927C | Missense Mutation (SNP) | VAF 152/600 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs913278695, COSV101459003; called by muse, mutect2, varscan2
- ZNF469 | c.4531G>A p.A1511T (on ENST00000437464; = p.A1539T on NM_001367624.2) | Missense Mutation (SNP) | VAF 118/455 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs559565235, COSV71259209; called by muse, mutect2, varscan2
- ZNF497 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 119/386 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs546643808; called by muse, mutect2, varscan2
- ZNF516 | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs549531434; called by muse, mutect2, varscan2
- ZNF525 | c.1030T>G p.C344G | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.098); catalogued as rs777216584; called by muse, mutect2
- ZNF536 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 156/584 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293606470, COSV62821318; called by muse, varscan2
- ZNF610 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs758475631, COSV58345357; called by muse, mutect2, varscan2
- ZNF724 | c.345del p.G116Afs*22 | Frame Shift Del (DEL) | VAF 42/191 reads (22%) | catalogued as rs781412139; called by mutect2, pindel, varscan2
- ZNF790 | c.528del p.A178Pfs*13 | Frame Shift Del (DEL) | VAF 58/345 reads (17%) | catalogued as rs1284301444; called by mutect2, pindel, varscan2
- ZNF862 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 146/548 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs370138647; called by muse, mutect2, varscan2
- ZSWIM8 | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 85/293 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs369888275; called by muse, mutect2, varscan2
- ZSWIM9 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 121/516 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs982996100; called by muse, mutect2, varscan2
- ZXDA | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 133/522 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV62387743; called by muse, mutect2, varscan2
- ABCC3 | c.268del p.Y90Tfs*33 | Frame Shift Del (DEL) | VAF 103/398 reads (26%) | called by mutect2, pindel, varscan2
- ABCD2 | c.2018A>G p.H673R | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACAD11 | c.2127G>A p.M709I | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ACOT8 | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACRBP | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 89/336 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ACTL7B | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 97/484 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM22 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS14 | c.1136T>C p.L379P | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ADAMTSL3 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ADCY5 | c.3400_3417del p.G1134_T1139del | In Frame Del (DEL) | VAF 58/267 reads (22%) | called by mutect2, pindel, varscan2
- ADGRF5 | c.3104C>A p.A1035D | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- AFG3L2 | c.255del p.A86Lfs*99 | Frame Shift Del (DEL) | VAF 26/154 reads (17%) | called by mutect2, varscan2
- AGAP9 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- AL451106.1 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 60/334 reads (18%) | called by muse, varscan2
- AL592490.1 | c.1930T>G p.F644V | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALAS1 | c.619dup p.I207Nfs*2 | Frame Shift Ins (INS) | VAF 36/142 reads (25%) | called by mutect2, varscan2
- ALOX12B | c.1965G>T p.E655D | Missense Mutation (SNP) | VAF 30/562 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- ALS2 | c.2608G>A p.D870N | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ANK3 | c.12225A>C p.K4075N | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ANKRD11 | c.2947A>G p.S983G | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD34C | c.314T>C p.L105S | Missense Mutation (SNP) | VAF 178/414 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANP32A | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 22/140 reads (16%) | called by mutect2, varscan2
- AP3B2 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- APC | c.4393_4394dup p.S1465Rfs*9 | Frame Shift Ins (INS) | VAF 70/388 reads (18%) | called by mutect2, varscan2
- AQR | c.464A>T p.N155I | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- AR | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 100/469 reads (21%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP26 | c.2077T>C p.S693P | Missense Mutation (SNP) | VAF 80/421 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP35 | c.3756_3758del p.T1253del | In Frame Del (DEL) | VAF 48/246 reads (20%) | called by pindel, varscan2
- ARHGEF17 | c.3713T>C p.L1238P | Missense Mutation (SNP) | VAF 58/442 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ARHGEF18 | c.2606G>A p.R869H (on ENST00000359920 / NM_001130955.2; = p.R765H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/477 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ARHGEF7 | c.1709T>C p.V570A (on ENST00000375741 / NM_001113511.2; = p.V392A on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ARID2 | c.2173del p.Q725Rfs*33 | Frame Shift Del (DEL) | VAF 92/403 reads (23%) | called by mutect2, pindel, varscan2
- ARIH1 | c.1523A>G p.Y508C | Missense Mutation (SNP) | VAF 116/249 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ARMC9 | c.2235G>T p.Q745H | Missense Mutation (SNP) | VAF 122/409 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARSK | c.987del p.M329Ifs*11 | Frame Shift Del (DEL) | VAF 59/293 reads (20%) | called by mutect2, pindel, varscan2
- ARV1 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ASB5 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATAD2B | c.1247T>C p.V416A | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATCAY | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ATG2A | c.4864C>T p.P1622S | Missense Mutation (SNP) | VAF 100/344 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ATP2C2 | c.1027_1029del p.V343del | In Frame Del (DEL) | VAF 36/169 reads (21%) | called by pindel, varscan2
- ATP6V0D2 | c.817-1G>T p.X273_splice | Splice Site (SNP) | VAF 54/294 reads (18%) | called by muse, mutect2, varscan2
- ATP6V1B1 | c.1446dup p.K483Qfs*28 | Frame Shift Ins (INS) | VAF 75/347 reads (22%) | called by mutect2, pindel, varscan2
- ATXN7 | c.2333del p.G778Afs*14 | Frame Shift Del (DEL) | VAF 116/454 reads (26%) | called by mutect2, pindel, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 134/426 reads (31%) | called by pindel, varscan2
- B4GALNT4 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 98/540 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, varscan2
- BABAM2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.034); called by muse, mutect2
- BACH2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 126/465 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- BAG6 | c.3496C>T p.Q1166* (on ENST00000676571; = p.Q1119* on NM_080702.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 100/381 reads (26%) | called by muse, mutect2, varscan2
- BECN2 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 94/415 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BECN2 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 119/444 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- BEND4 | c.264del p.G91Afs*23 | Frame Shift Del (DEL) | VAF 28/166 reads (17%) | called by pindel, varscan2
- BLOC1S4 | c.131G>A p.W44* | Nonsense Mutation (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- BNIPL | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- BOD1L1 | c.1707del p.V570* | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | called by mutect2, varscan2
- BPIFB1 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- BRINP2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 16/488 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BRSK2 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- C14orf93 | c.785A>G p.D262G | Missense Mutation (SNP) | VAF 31/588 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); called by muse, mutect2
- C1QTNF9B | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 88/749 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- C3orf80 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, varscan2
- C5 | c.4765G>A p.E1589K | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C5orf34 | c.1864dup p.T622Nfs*3 | Frame Shift Ins (INS) | VAF 40/170 reads (24%) | called by mutect2, varscan2
- C7orf33 | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C8orf58 | c.1047G>A p.M349I (on ENST00000289989 / NM_001013842.3; = p.M341I on NM_173686.3) | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2
- CACNA1B | c.4061C>T p.A1354V | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CACNA1I | c.6481G>A p.A2161T | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNG2 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CACNG4 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 45/273 reads (16%) | called by muse, mutect2, varscan2
- CARMIL2 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 87/330 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CATSPERB | c.1319T>C p.F440S | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAVIN3 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 71/403 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC110 | c.1605G>C p.E535D | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC120 | c.923T>A p.V308D | Missense Mutation (SNP) | VAF 112/460 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 72/165 reads (44%) | called by mutect2, varscan2
- CCDC18 | c.3297dup p.E1100Rfs*3 (on ENST00000343253 / NM_001306076.1; = p.E1101Rfs*3 on NM_206886.4) | Frame Shift Ins (INS) | VAF 36/203 reads (18%) | called by mutect2, pindel, varscan2
- CCDC180 | c.3621G>T p.E1207D | Missense Mutation (SNP) | VAF 107/362 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CCDC189 | c.469+3G>A | Splice Region (SNP) | VAF 93/403 reads (23%) | called by muse, mutect2, varscan2
- CCT3 | c.1518_1520del p.Y506_K507delins* | Nonsense Mutation (DEL) | VAF 48/202 reads (24%) | called by mutect2, pindel, varscan2
- CCT7 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 94/382 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- CDC40 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CDKL5 | c.2419T>A p.S807T | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- CDPF1 | c.149del p.F50Sfs*80 | Frame Shift Del (DEL) | VAF 52/330 reads (16%) | called by mutect2, pindel, varscan2
- CDYL | c.1630A>G p.N544D (on ENST00000328908 / NM_001368125.1; = p.N490D on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2
- CENPC | c.2272T>C p.Y758H | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP126 | c.248del p.A84Lfs*57 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, pindel, varscan2
- CEP170B | c.2914C>T p.P972S (on ENST00000453495; = p.P901S on NM_015005.3) | Missense Mutation (SNP) | VAF 155/584 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CEP250 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CEP250 | c.4175del p.N1392Mfs*4 | Frame Shift Del (DEL) | VAF 94/358 reads (26%) | called by mutect2, pindel, varscan2
- CEP85L | c.1103_1105del p.E368del | In Frame Del (DEL) | VAF 21/123 reads (17%) | called by pindel, varscan2
- CHAF1A | c.2810del p.G937Vfs*12 | Frame Shift Del (DEL) | VAF 67/292 reads (23%) | called by mutect2, pindel, varscan2
- CHD9 | c.2108del p.K703Rfs*7 | Frame Shift Del (DEL) | VAF 33/164 reads (20%) | called by mutect2, pindel, varscan2
- CHRNA7 | c.298_299del p.V100Sfs*16 | Frame Shift Del (DEL) | VAF 58/278 reads (21%) | called by mutect2, pindel, varscan2
- CHST14 | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIAO3 | c.436del p.I146* | Frame Shift Del (DEL) | VAF 41/144 reads (28%) | called by mutect2, pindel, varscan2
- CIITA | c.3082A>G p.T1028A | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CLASP1 | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLSTN2 | c.333dup p.I112Hfs*2 | Frame Shift Ins (INS) | VAF 84/404 reads (21%) | called by mutect2, pindel, varscan2
- CLUL1 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 84/285 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CNNM1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 111/435 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CNTN4 | c.1511del p.P504Lfs*18 | Frame Shift Del (DEL) | VAF 50/213 reads (23%) | called by mutect2, pindel, varscan2
- COL20A1 | c.3475G>T p.G1159W | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A3 | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A1 | c.5409C>G p.D1803E | Missense Mutation (SNP) | VAF 73/369 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- COL8A1 | c.2015del p.G672Afs*14 | Frame Shift Del (DEL) | VAF 60/298 reads (20%) | called by mutect2, varscan2
- COMP | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.011); called by muse, varscan2
- COPA | c.512del p.N171Tfs*11 | Frame Shift Del (DEL) | VAF 58/242 reads (24%) | called by mutect2, varscan2
- CORO1B | c.827A>G p.D276G | Missense Mutation (SNP) | VAF 90/341 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CPD | c.690dup p.A231Rfs*38 | Frame Shift Ins (INS) | VAF 39/183 reads (21%) | called by mutect2, pindel, varscan2
- CPN1 | c.1136T>G p.L379R | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRB2 | c.3062G>A p.G1021D | Missense Mutation (SNP) | VAF 77/457 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CROCC | c.3317A>G p.D1106G | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CRTAM | c.203del p.N68Ifs*21 | Frame Shift Del (DEL) | VAF 35/140 reads (25%) | called by mutect2, pindel, varscan2
- CRYGN | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 93/374 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTBP2 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CUL1 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CUL1 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL5 | c.1694del p.N565Ifs*18 | Frame Shift Del (DEL) | VAF 98/193 reads (51%) | called by mutect2, varscan2
- CYP11A1 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 17/363 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.024); called by muse, mutect2
- CYP26C1 | c.15del p.L6* | Frame Shift Del (DEL) | VAF 65/327 reads (20%) | called by mutect2, pindel, varscan2
- CYP2R1 | c.720del p.F240Lfs*13 | Frame Shift Del (DEL) | VAF 39/250 reads (16%) | called by mutect2, pindel, varscan2
- DAB2IP | c.520A>G p.T174A (on ENST00000408936; = p.T146A on NM_032552.3) | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- DACT3 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.365); called by muse, varscan2
- DACT3 | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 61/342 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, varscan2
- DAPK1 | c.3914T>C p.L1305P | Missense Mutation (SNP) | VAF 100/441 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- DCD | c.83dup p.G29Rfs*8 | Frame Shift Ins (INS) | VAF 68/275 reads (25%) | called by mutect2, pindel, varscan2
- DCDC2 | c.1105A>T p.M369L | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCN | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- DDB1 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- DDC | c.1297del p.I433Sfs*98 | Frame Shift Del (DEL) | VAF 68/304 reads (22%) | called by mutect2, pindel, varscan2
- DDR1 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 179/608 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DDX19A | c.725A>C p.E242A | Missense Mutation (SNP) | VAF 76/396 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DDX24 | c.17_18del p.T6Kfs*29 | Frame Shift Del (DEL) | VAF 47/274 reads (17%) | called by pindel, varscan2
- DENND4A | c.5299A>G p.M1767V | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- DENND5B | c.3251dup p.N1084Kfs*26 | Frame Shift Ins (INS) | VAF 32/176 reads (18%) | called by mutect2, pindel, varscan2
831 further variants in this file (411 protein-altering or splice-affecting, 371 silent, 49 other) are not listed here.
